Gene-level copy-number profile of tumor specimen TCGA-VS-A8QF-01A from TCGA case TCGA-VS-A8QF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 42.1 years (15,374 days).
Specimen TCGA-VS-A8QF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.a94dc00e-54ef-4523-8df1-d077dabaa0f7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A8QF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e7d9452-5c6a-4628-b8b6-f4d7ffe3cf16

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 398; copy number 2: 10,264; copy number 3: 28,254; copy number 4: 13,270; copy number 5: 3,623; copy number 6: 3,384; copy number 7: 98; copy number 8: 369; copy number 11: 102; copy number 12: 16; copy number 14: 3; copy number 18: 5; copy number 20: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A8QF-01A-21D-A37M-01): tumor purity 0.7, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:39,873,782–40,112,599, 3 genes: AC021749.1, AC021820.1, AC080100.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 613 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:42,380,792–44,390,823, 90 genes, copy number 8 (broad region; genes not listed).
- chr1:47,688,463–48,263,179, 13 genes, copy number 7: LINC01738, TRABD2B, AL691459.1, AC096541.1, LINC02794, AL356289.1, CYP46A4P, SKINT1L, AL356289.2, AL109659.1, SLC5A9, AL109659.2, AL109659.3.
- chr1:52,345,723–56,524,495, 120 genes, copy number 8 (broad region; genes not listed).
- chr1:56,538,452–56,538,911, 1 gene, copy number 8: RPL21P23.
- chr1:58,047,889–61,589,904, 40 genes, copy number 8: HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.3, AC099791.4.
- chr1:111,989,770–111,998,842, 1 gene, copy number 7: LINC01750.
- chr2:9,740,643–9,770,341, 3 genes, copy number 14: RNU4-73P, AC082651.2, AC082651.3.
- chr2:177,111,036–183,215,414, 103 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr11:99,020,949–100,358,885, 1 gene, copy number 7 (within-gene range 4–7): CNTN5.
- chr11:100,336,856–102,836,766, 43 genes, copy number 7 (within-gene range 2–7): RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2.
- chr12:28,978,584–30,130,590, 15 genes, copy number 8 (within-gene range 6–8): AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99, AC023511.3.
- chr15:71,096,952–71,783,383, 1 gene, copy number 7 (within-gene range 4–7): THSD4.
- chr15:71,147,650–71,549,832, 5 genes, copy number 7: THSD4-AS1, HMGB1P6, AC064799.2, AC064799.1, AC108861.1.
- chr18:3,025,069–6,108,382, 54 genes, copy number 7–18 (within-gene range 1–18): AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1, EPB41L3, AP005059.2, AP005059.1, MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3.
- chr18:5,956,101–5,960,785, 1 gene, copy number 7: AP001021.2.
- chr19:37,497,159–39,738,029, 122 genes, copy number 11–20 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 397. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
